Somatic mutation profile of tumor specimen C3N-02696-02 (aliquot CPT0187720032) from CPTAC case C3N-02696, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.2 years (23,828 days).
Specimen C3N-02696-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81689fd5-7a96-4a01-a775-ff61bde5c25e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02696-31 (Blood Derived Normal), aliquot CPT0187770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bde7406d-0c76-46e7-9ea4-1af4138949f2

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 5'UTR 3, Silent 2, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPNT1 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | catalogued as COSV104398019; called by muse, mutect2
- CDCA3 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1555125529; called by muse, mutect2
- REXO5 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs374414245; called by muse, mutect2, varscan2
- SLIT1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as rs373698645; called by muse, mutect2
- USP17L2 | c.1227G>C p.K409N | Missense Mutation (SNP) | VAF 87/2123 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs774997041, COSV100414518; called by muse, mutect2
- ANKRD26 | c.3855G>C p.E1285D | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2
- CAPN11 | c.1162A>G p.S388G | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- CFAP52 | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2
- LONP1 | c.1616C>G p.A539G | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- P2RX2 | c.761A>T p.E254V (on ENST00000343948 / NM_170683.4; = p.E182V on NM_012226.5) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PXDN | c.2093T>A p.L698H | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); called by muse, mutect2
- SCAPER | c.875C>A p.T292K | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.012); called by muse, mutect2
- SP100 | c.2528A>G p.N843S | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); called by muse, mutect2
- SPEN | c.4345G>A p.E1449K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TNFAIP3 | c.1778A>C p.Q593P | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- ZNF142 | c.2888C>T p.S963F (on ENST00000411696 / NM_001379660.1; = p.S763F on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.673); called by muse, mutect2
- CHRNB2 | c.1164G>A p.T388= | Silent (SNP) | VAF 22/345 reads (6%) | catalogued as rs1442840929; called by muse, mutect2
- GALNT12 | c.480T>G p.L160= | Silent (SNP) | VAF 13/191 reads (7%) | catalogued as COSV66663585; called by muse, mutect2
- CNKSR3 | c.-5T>G | 5'UTR (SNP) | VAF 18/271 reads (7%) | called by muse, mutect2
- CREBBP | c.-78G>T | 5'UTR (SNP) | VAF 17/128 reads (13%) | catalogued as rs940136901; called by muse, mutect2, varscan2
- FAM76A | c.-51A>G | 5'UTR (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- PXT1 | c.*41T>C | 3'UTR (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2
- TPO | c.2748+17C>T | Intron (SNP) | VAF 26/354 reads (7%) | catalogued as rs778044030; called by muse, mutect2
- XKR4 | c.806+58310C>T | Intron (SNP) | VAF 31/222 reads (14%) | catalogued as rs940389590, COSV100534470; called by muse, mutect2, varscan2
